Surgical pathology report (de-identified scan), TCGA case TCGA-DK-AA71, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DK-AA71-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY REPORT

Patient Name:

Accession #:

Med. Rec. #:

Date of Procedure:

DOB: (Age)

Location:

Date of Receipt:

Gender:

M

Service:

Urology

Date of Report:

Ref. Physician:

Account #:

Patient Address:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

T1HG per TUR-BT, large volume tumor, possible extra bladder extension per imaging

Specimens Submitted:

- 1: Urethral margin (fs)
- 2: Right common iliac lymph node
- 3: Left common iliac lymph node
- 4: Right distal pelvic lymph node
- 5: Left distal pelvic lymph node
- 6: Bladder, prostate, seminal vesicles, peri vesicle lymph nodes
- 7: Presacral lymph nodes
- 8: Right distal pelvic lymph nodes #2
- 9: Distal left ureter
- 10: Distal right ureter

ICD-0-3

carcinoma, urothelial, NOS 8120/3

Site: bladder, lateral wall, NOS C67.2

fw
4/15/14

DIAGNOSIS:

1. Urethral margin (fs):

Benign urothelium and prostatic tissue

2. Right common iliac lymph node:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 4

3. Left common iliac lymph node:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 3

4. Right distal pelvic lymph node:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 8

5. Left distal pelvic lymph node:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 6

6. Bladder, prostate, seminal vesicles, peri vesicle lymph nodes:

a.

Tumor Type:

Urothelial carcinoma with squamous differentiation

Histologic Grade:

High grade

Pattern of growth of the Non-Invasive component:

Papillary and flat

Pw TSS, squamous differentiation = < 5%.

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Pattern of growth of the Invasive component:

Infiltrating

Tumor Multicentricity:

Not identified

Bladder Local Invasion:

Deep half of muscularis propria

Extravesical Tumor Extension:

Ureters uninvolved

Urethra uninvolved

Vascular Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Non-Neoplastic Mucosa:

Exhibiting chronic cystitis

Exhibiting ulceration

Prostate:

Other See prostate template below

Seminal Vesicles:

Not involved

Perivesical Lymph Nodes:

Not identified

The Pathologic Stage is (AJCC 2002):

pT2b (Invades deep half of muscularis propria)

PR0 (No involvement of prostate)

b.

Tumor Type:

Adenocarcinoma

Gleason's Grade:

Primary Gleason grade:3

Secondary Gleason grade:4

Total Gleason score:7

Tumor Location:

Dominant tumor mass located in: left posterior apex

Vascular Invasion:

Not Identified

Perineural Invasion:

Not identified

Tumor Multicentricity:

Not identified

High Grade Prostatic Intraepithelial Neoplasia:

Identified

Capsule:

Tumor confined to prostate

Seminal Vesicles:

Not involved

Bladder Neck:

Not Involved

Surgical Margins:

Free of tumor

Non-Neoplastic Prostate:

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Exhibits nodular hyperplasia

Staging (AJCC 1997):

pT2a (confined to the prostate & capsule, involving one lobe)

7. Presacral lymph nodes:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 1

8. Right distal pelvic lymph nodes #2:

Lymph Node Dissection:

Benign lymph nodes

Number of lymph nodes examined: 2

9. Distal left ureter:

Segment of benign and inflamed ureter

10. Distal right ureter:

Segment of benign and inflamed ureter

Note:

Immunostains D2-40 and ERG were used to assess the presence of lymphovascular invasion.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the Department of Pathology. They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Urethral margin " and consists of a tan pink piece of soft tissue measuring 1.2 X 1.2 X 0.3 cm. Entirely submitted for frozen section. Summary of sections: FSC – frozen section control

2) The specimen is received fresh, labeled "Right common iliac lymph nodes" and consists of five pink tan firm, fatty lymph nodes ranging from 0.5 to 2.7 cm in greatest dimension. All identified lymph nodes are submitted.
Summary of sections: LN - lymph nodes, BL1 – BLN3 - bisected lymph nodes #1-3

3) The specimen is received fresh, labeled "Left common iliac lymph node" and consists of six pink tan firm, fatty lymph nodes ranging from 0.6 to 2.5 cm in greatest dimension. All identified lymph nodes are submitted.
Summary of sections: LN - lymph nodes, BLN - bisected lymph node

4) The specimen is received fresh, labeled "Right distal pelvic lymph nodes" and consists of eight pink tan firm, fatty lymph nodes ranging from 0.6 to 3.5 cm in greatest dimension. All identified lymph nodes are submitted.
Summary of sections: LN - lymph nodes, BLN - bisected lymph nodes, TLN – trisected lymph node
QL1 – quadrisected lymph node #1, QL2 – quadrisected lymph node #2

5) The specimen is received fresh, labeled "Left distal pelvic lymph nodes" and consists of thirteenth pink tan firm, fatty lymph nodes ranging from 0.6 to 3.2 cm in greatest dimension. All identified lymph nodes are submitted.

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

Summary of sections: LN - lymph nodes, BLN - bisected lymph nodes, QLN – quadrisected lymph node

6) The specimen is received fresh, labeled "Bladder prostate, seminal vesicles and perivesicular lymph nodes". It consists of a bladder with attached prostate and adnexa measuring 17 cm from superior to inferior, 9 cm laterally and 8 cm from anterior to posterior. The bladder measures 13.5 x 9.5 x 9 cm and is markedly distorted with an underlying non palpable mass. The prostate measures 4.5 x 4 x 3.8 cm. The right half of the prostate is inked green; the left half of the prostate is inked blue. The anterior aspect of the bladder is inked black and the posterior blue. The prostatic urethral margin is shaved and submitted. The bladder is opened along the anterior midline to reveal a tan-yellow fungating predominately necrotic mass fulfilling the majority of the bladder cavity measuring 12.5 x 9.5 x 6.2 cm. The tumor is more closely associated with the left lateral wall, but extends into all regions of the bladder, completely covering the left anterior and posterior wall, dome mucosa. The attachment of the tumor to the bladder mucosa is a 1.1 cm from the right ureteral orifice, completely obliterating the left ureteral orifice and is 4.2 cm from the prosthetic urethral margin. The tumor is sectioned to reveal extension through the bladder wall into the perivesicular fat, predominantly to the left aspect. The remaining bladder mucosa at the right anterior/posterior wall and trigone is tan yellow and granular. The perivesicular fat is sectioned to reveal vascularity only. No perivesicular lymph nodes are identified. The prostate is serially sectioned to reveal a diffuse tan nodular parenchyma with an edematous left and right seminal vesicle. The tumor is 1.4cm from the underlying vasa deferentia. Representative sections are submitted. The specimen is photographed. TPS is submitted.

Summary of sections: UTHM - urethral margin, RUM - right ureter margin, LUM - left ureter margin, RUO - right ureter orifice, LUO - left ureter orifice, TAW - tumor to anterior wall and perivesicular fat, TPW - tumor to posterior wall and perivesicular fat, TF - tumor to perivesical fat, TVD - tumor to vasa deferentia, TRP - tumor to right posterior wall, TTTRI - tumor to trigone, RA - right anterior wall, RAP - right apex prostate, LAP - left apex prostate, RAM - right anterior mid prostate, RPM - right posterior mid prostate, LAM - left anterior mid prostate, LPM - left posterior mid prostate, RAB - right anterior base prostate, RPB - right posterior base prostate, LAB - left anterior base prostate, LPB - left posterior base prostate, RSV - right seminal vesicle, LSV - left seminal vesicle, ADD - additional sections of the base of the tumor

7) The specimen is received fresh, labeled "Presacral lymph nodes" and consists of four pink tan firm, fatty lymph nodes ranging from 0.7 to 3.2 cm in greatest dimension. All identified lymph nodes are submitted. Summary of sections: LN - lymph nodes

8) The specimen is received fresh, labeled "Right distal pelvic lymph nodes #2" and consists of a portion of yellow and tan adipose tissue, measuring 2.5 x 2.0 x 1.2cm, two pink tan firm, fatty lymph nodes are identified measuring 0.6 x 0.5 x 0.2 and 0.5 x 0.5 x 0.2 cm. All identified lymph nodes are submitted. Summary of sections: LN - lymph nodes

9) The specimen is received in formalin, labeled "Distal left ureter, unclipped end is margin" and consists of a tan-white tubular tissue fragment measuring 4.1 cm in length and 1.0 cm in average diameter, with attached adipose tissue measuring 0.5 cm in thickness. There is a clip at one end of the specimen. On cross sections, the mucosa appears grossly unremarkable. The specimen is sequentially sectioned from the clipped end to the non-clipped end and submitted entirely.

Summary of sections: CE = clipped end (inked black), NCE = non-clipped end (inked blue)

SS = sequential sections from clipped to non-clipped end

10) The specimen is received in formalin, labeled "Distal right ureter, unclipped end is margin" and consists of a tan-white tubular tissue fragment measuring 4.2 cm in length and 1.0 cm in average diameter, with attached adipose tissue measuring 0.6 cm in thickness. There is a clip at one end of the specimen. On cross sections, the mucosa appears grossly unremarkable. The specimen is sequentially sectioned from the clipped end to the non-clipped end and submitted entirely.

Summary of sections: CE = clipped end, NCE = non-clipped end, SS = sequential sections from clipped to non-clipped end

Summary of Sections:

Part 1: Urethral margin (fs)

Blocks	Block Designation	PCs
1	FSC	1

Part 2: Right common iliac lymph node

Blocks	Block Designation	PCs
1	BL1	2
1	BL2	2
2	BL3	2
1	LN	1

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

Part 3: Left common iliac lymph node

Blocks	Block Designation	PCs
1	BLN	2
3	LN	4

Part 4: Right distal pelvic lymph node

Blocks	Block Designation	PCs
4	BLN	8
1	LN	1
4	QL1	4
4	QL2	4
3	TLN	3

Part 5: Left distal pelvic lymph node

Blocks	Block Designation	PCs
3	BLN	6
3	LN	9
4	QLN	4

Part 6: Bladder, prostate, seminal vesicles, peri vesicle lymph nodes

Blocks	Block Designation	PCs
10	ADD	10
1	LAB	1
1	LAM	1
1	LAP	1
1	LPB	1
1	LPM	1
1	LSV	1
1	LUM	1
1	LUO	1
1	RA	1
1	RAB	1
1	RAM	1
1	RAP	1
1	RPB	1
1	RPM	1
1	RSV	1
1	RUM	1
1	RUO	1
4	TAW	4
1	TF	1
3	TPW	3
2	TRP	2
2	TTRI	2
1	TVD	1
1	UTHM	1

Part 7: Presacral lymph nodes

Blocks	Block Designation	PCs
2	LN	4

Part 8: Right distal pelvic lymph nodes #2

Blocks	Block Designation	PCs
1	LN	1

Part 9: Distal left ureter

Blocks	Block Designation	PCs
--------	-------------------	-----

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

1	CE	1
1	NCE	1
5	SS	10

Part 10: Distal right ureter

Blocks	Block Designation	PCs
1	CE	1
1	NCE	1
5	SS	11

Special Studies:

Result	Special Stain	Comment
	IMM RECUT	
	P16.	
	HPV	
	IMM RECUT	
	NEGATIVE.	
	ERG.	
	D2-40	
	ERG.	
	D2-40	
	IMM RECUT	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: Benign ()
PERMANENT DIAGNOSIS: same

Source: NCI Genomic Data Commons file 9ee4c6a1-4a41-47a1-9766-0021483e603e (TCGA-DK-AA71.5C8A75F5-A08D-4CA9-A3D3-67F77C4A65EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).